Somatic mutation profile of tumor specimen TCGA-10-0934-01A (aliquot TCGA-10-0934-01A-02W-0420-08) from TCGA case TCGA-10-0934, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,602 days).
Specimen TCGA-10-0934-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6939a22-a6b3-4257-bbab-ee3e80d199ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0934-11A (Solid Tissue Normal), aliquot TCGA-10-0934-11A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f46af25-c5bf-4e4f-a542-f86b4545f418

The open-access MAF lists 77 somatic variants for this specimen: 69 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 45, Missense Mutation 22, Silent 6, Intron 1, Nonsense Mutation 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 42/374 reads (11%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 73/302 reads (24%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL5A1 | c.2988dup p.G997Rfs*17 | Frame Shift Ins (INS) | VAF 14/130 reads (11%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 17/132 reads (13%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 39/334 reads (12%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707dup | Intron (INS) | VAF 34/186 reads (18%) | catalogued as rs747392139; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 346/801 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 576/1420 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 42/324 reads (13%) | catalogued as rs3215969; called by mutect2, varscan2
- ARHGEF7 | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as rs746874740, COSV100404454, COSV57730780; called by muse, varscan2
- CCDC27 | c.1915dup p.L639Pfs*? | Frame Shift Ins (INS) | VAF 20/136 reads (15%) | catalogued as rs751021664; called by mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | catalogued as rs773511514; called by mutect2, varscan2
- CHSY1 | c.666dup p.P223Afs*29 | Frame Shift Ins (INS) | VAF 14/122 reads (11%) | catalogued as rs762321510; called by mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 92/808 reads (11%) | catalogued as rs767756120; called by mutect2, varscan2
- DCUN1D4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs758671159, COSV58121065; called by muse, mutect2, varscan2
- DLGAP3 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1291733500, COSV52391941; called by muse, mutect2, varscan2
- DNMBP | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs547189728, COSV60621466; called by muse, mutect2, varscan2
- FAM104A | c.268dup p.Q90Pfs*6 | Frame Shift Ins (INS) | VAF 22/174 reads (13%) | catalogued as rs769947396; called by mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 22/178 reads (12%) | catalogued as rs768450027; called by mutect2, varscan2
- GEN1 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183092755, COSV100437752, COSV58056387; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | catalogued as rs749150409; called by mutect2, varscan2
- IKBKB | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 101/741 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.209); catalogued as rs768016671, COSV60596075; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 63/348 reads (18%) | catalogued as rs780982673; called by mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 67/348 reads (19%) | catalogued as rs761558950; called by mutect2, varscan2
- KCNH2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764666519, COSV51132535; called by muse, mutect2, varscan2
- KCNH4 | c.2397dup p.R800Qfs*33 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs778022334; called by mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 37/302 reads (12%) | catalogued as rs750932259; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 69/360 reads (19%) | catalogued as rs757410385; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 90/406 reads (22%) | catalogued as rs777328830; called by mutect2, varscan2
- MIDEAS | c.106dup p.Q36Pfs*33 | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | catalogued as rs760940567; called by mutect2, varscan2
- MTMR10 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as rs771732352, COSV71188782; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 16/154 reads (10%) | catalogued as rs772439983; called by mutect2, varscan2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 39/294 reads (13%) | catalogued as rs763440516; called by mutect2, varscan2
- NOTUM | c.704dup p.T236Hfs*12 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | catalogued as rs778719752; called by mutect2, pindel, varscan2
- OR4C11 | c.779dup p.T261Dfs*53 | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | catalogued as rs764963140; called by mutect2, pindel
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 30/248 reads (12%) | catalogued as rs780916980; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 156/1160 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 74/400 reads (19%) | catalogued as rs768056539; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 238/1646 reads (14%) | catalogued as rs778683789; called by mutect2, varscan2
- PTX4 | c.1191dup p.G398Rfs*? (on ENST00000447419 / NM_001328608.2; = p.G393Rfs*? on NM_001013658.1) | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs772722517; called by mutect2, varscan2
- RAPH1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV100052034; called by muse, mutect2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 56/250 reads (22%) | catalogued as rs762949421; called by mutect2, varscan2
- ROBO3 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1189571607, COSV67299601; called by muse, varscan2
- SEZ6 | c.915dup p.P306Afs*2 | Frame Shift Ins (INS) | VAF 20/128 reads (16%) | catalogued as rs766332422; called by mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 145/737 reads (20%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC4A1AP | c.416dup p.T140Dfs*43 | Frame Shift Ins (INS) | VAF 11/109 reads (10%) | catalogued as rs757574852; called by mutect2, pindel, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 16/135 reads (12%) | catalogued as rs748701652; called by mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 22/178 reads (12%) | catalogued as rs746816975; called by mutect2, varscan2
- SPAST | c.209A>C p.H70P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100188286; called by muse, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 36/250 reads (14%) | catalogued as rs748467821; called by mutect2, varscan2
- SRD5A2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 666/1362 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1418439291, COSV51870651; called by muse, mutect2, varscan2
- SRGAP3 | c.2548dup p.V850Gfs*10 | Frame Shift Ins (INS) | VAF 28/228 reads (12%) | catalogued as rs759698239; called by mutect2, varscan2
- TAF1L | c.4744C>A p.Q1582K | Missense Mutation (SNP) | VAF 47/1826 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.323); catalogued as COSV54270534; called by muse, mutect2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 91/506 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TET2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV99480562; called by muse, mutect2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 104/604 reads (17%) | catalogued as rs782753958; called by mutect2, varscan2
- TNS3 | c.4231A>G p.T1411A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1372561914, COSV60787600; called by muse, mutect2, varscan2
- USP19 | c.1145dup p.L383Pfs*47 | Frame Shift Ins (INS) | VAF 13/86 reads (15%) | catalogued as rs775252063; called by mutect2, varscan2
- USP31 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.45); catalogued as COSV54849851; called by muse, mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | catalogued as rs750038548; called by mutect2, varscan2
- XKR6 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs201821196; called by muse, mutect2, varscan2
- ZMYND19 | c.236dup p.V80Rfs*34 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | catalogued as rs753541275; called by mutect2, varscan2
- ZSWIM8 | c.5085dup p.Y1696Lfs*3 (on ENST00000605216 / NM_001242487.2; = p.Y1701Lfs*3 on NM_015037.3) | Frame Shift Ins (INS) | VAF 67/328 reads (20%) | catalogued as rs769663113; called by mutect2, varscan2
- CCNJ | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FBN3 | c.7912C>T p.Q2638* | Nonsense Mutation (SNP) | VAF 25/422 reads (6%) | called by muse, mutect2
- GARRE1 | c.697dup p.A233Gfs*3 | Frame Shift Ins (INS) | VAF 10/102 reads (10%) | called by mutect2, pindel
- INSR | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RAPGEF5 | c.736C>T p.H246Y (on ENST00000401957 / NM_001367602.2; = p.H549Y on NM_012294.5) | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- UPK1A | c.252_254dup p.A85dup | In Frame Ins (INS) | VAF 12/126 reads (10%) | called by mutect2, pindel
- ANKLE2 | c.2589G>T p.L863= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV63294512; called by muse, mutect2, varscan2
- PKHD1L1 | c.4443C>T p.S1481= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs763983259, COSV65738582; called by muse, mutect2
- PROX1 | c.387C>T p.C129= | Silent (SNP) | VAF 124/1105 reads (11%) | catalogued as rs1470009852, COSV54775476; called by muse, mutect2, varscan2
- PRX | c.1647G>A p.P549= | Silent (SNP) | VAF 167/366 reads (46%) | catalogued as rs202113722, COSV52527803, COSV52528592; called by muse, mutect2, varscan2
- SMPD1 | c.1446C>T p.F482= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as CM023157; called by muse, mutect2
- ZNF714 | c.879T>A p.A293= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV52510088; called by muse, mutect2, varscan2
- ELK1 | c.-78dup | 5'UTR (INS) | VAF 12/98 reads (12%) | catalogued as rs766410990; called by mutect2, pindel
